Somatic mutation profile of tumor specimen TCGA-DM-A280-01A (aliquot TCGA-DM-A280-01A-12D-A16V-10) from TCGA case TCGA-DM-A280, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,649 days).
Specimen TCGA-DM-A280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c82fd285-a4db-4a2a-a765-7401911a6728.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A280-10A (Blood Derived Normal), aliquot TCGA-DM-A280-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d023d049-1aa6-474c-aecc-102a8df7b279

The open-access MAF lists 129 somatic variants for this specimen: 91 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 32, Intron 6, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 12/132 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NEB | c.10435C>T p.R3479* | Nonsense Mutation (SNP) | VAF 29/166 reads (17%) | catalogued as rs928945364, CM1413904, COSV51267780; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- SMAD3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906850, CM110722, COSV59286247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- ADAMTS2 | c.2924G>T p.C975F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281817; called by muse, mutect2, varscan2
- ADGRL4 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100875866, COSV66060392; called by muse, mutect2, varscan2
- ADNP2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100080763, COSV51540861; called by muse, mutect2, varscan2
- AKAP6 | c.5075G>A p.S1692N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99800188; called by muse, mutect2, varscan2
- AMIGO2 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99873577; called by mutect2, varscan2
- APC | c.4358del p.P1453Lfs*20 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as COSV57380306; called by mutect2, pindel, varscan2
- ATAD2B | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | catalogued as COSV99477505; called by muse, mutect2, varscan2
- ATP6AP1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1302676187, COSV100870672; called by muse, mutect2, varscan2
- CACNA2D3 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs775717340, COSV55530928; called by muse, mutect2, varscan2
- CFAP54 | c.8107T>G p.L2703V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.542); catalogued as COSV100733101; called by muse, mutect2, varscan2
- CFH | c.3431T>G p.L1144R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66407723; called by muse, mutect2, varscan2
- COPS6 | c.426G>A p.V142= | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as rs371629256, COSV100384852; called by mutect2, varscan2
- CPNE2 | c.780G>A p.P260= | Splice Region (SNP) | VAF 7/37 reads (19%) | catalogued as rs374498654; called by muse, mutect2, varscan2
- CRYBA2 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV99838071; called by muse, mutect2, varscan2
- CSF3R | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765606679, COSV100117595; called by mutect2, varscan2
- DCLK1 | c.1580A>C p.K527T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99710533; called by muse, mutect2, varscan2
- EFCAB14 | c.604T>G p.L202V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV64238878; called by muse, mutect2, varscan2
- EPS15L1 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780582035, COSV50167106; called by muse, mutect2, varscan2
- ERBB4 | c.3304T>G p.F1102V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100725095; called by muse, mutect2
- FAM47C | c.705C>A p.H235Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV100792459; called by muse, varscan2
- FAT3 | c.13526C>A p.S4509Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV53105132; called by muse, mutect2, varscan2
- FAT4 | c.12008A>C p.K4003T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV100627905; called by muse, mutect2
- FBN2 | c.8510C>A p.S2837Y | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV52510087, COSV52533004; called by muse, mutect2, varscan2
- FOXN1 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV99881191; called by muse, mutect2, varscan2
- GLT6D1 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874523; called by muse, mutect2, varscan2
- GREB1 | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs371773393; called by muse, varscan2
- GRIA2 | c.1801T>C p.S601P | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52408190, COSV99644042; called by muse, mutect2, varscan2
- GRIA2 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV52381695, COSV99644046; called by mutect2, varscan2
- HAGH | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV101272452; called by muse, mutect2, varscan2
- HMCN1 | c.3727G>T p.A1243S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99627901; called by muse, mutect2, varscan2
- HMCN1 | c.16314T>A p.N5438K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV99627904; called by muse, mutect2, varscan2
- IL21R | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs746751826, COSV61970086; called by muse, mutect2, varscan2
- KCNA4 | c.1831T>A p.Y611N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV100068845, COSV60255068; called by muse, mutect2, varscan2
- KCNK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57279943; called by muse, mutect2, varscan2
- LAMA4 | c.2147T>G p.V716G (on ENST00000230538 / NM_001105206.3; = p.V709G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV100038189; called by muse, mutect2, varscan2
- LATS2 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs915063122, COSV66879137; called by muse, mutect2, varscan2
- LPA | c.2966G>T p.C989F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100306663; called by mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- MARK1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1365446821, COSV65066139; called by muse, mutect2, varscan2
- MBD6 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.867); catalogued as rs751486226, COSV100851637; called by mutect2, varscan2
- MMP19 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100491075; called by muse, mutect2, varscan2
- MTCL1 | c.4574C>T p.T1525M (on ENST00000306329 / NM_001378206.1; = p.T1206M on NM_015210.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs377453546; called by mutect2, varscan2
- MYCBP2 | c.1904-11_1913del p.X635_splice (on ENST00000357337; = p.X673_splice on NM_015057.5) | Splice Site (DEL) | VAF 10/90 reads (11%) | catalogued as COSV62017327; called by mutect2, pindel
- NADK | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1557829238, COSV58272794; called by muse, mutect2, varscan2
- NOS3 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52492459, COSV99871523; called by mutect2, varscan2
- NYAP2 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV56015052, COSV99796348; called by muse, mutect2, varscan2
- OR13C4 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52925949, COSV52926506; called by muse, mutect2, varscan2
- PCDH11X | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100011077, COSV53498694; called by mutect2, varscan2
- PCDHB7 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.422); catalogued as rs782137017, COSV50757033; called by muse, mutect2, varscan2
- PCDHGB3 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1356190228, COSV53918744; called by muse, mutect2, varscan2
- PEG3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs763208406, COSV55632441; called by muse, mutect2, varscan2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 64/184 reads (35%) | catalogued as rs1356026422; called by mutect2, varscan2
- POU3F4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs1387725375, COSV64538791, COSV64540956; called by muse, mutect2, varscan2
- POU6F2 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV101302607; called by muse, varscan2
- PPARA | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747200358, COSV99415396; called by mutect2, varscan2
- PRICKLE2 | c.343G>A p.E115K (on ENST00000295902; = p.E59K on NM_198859.4) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV55769958; called by muse, mutect2, varscan2
- PWP1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101338809; called by muse, mutect2, varscan2
- RPGRIP1L | c.1243+2T>C p.X415_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100046204; called by muse, mutect2, varscan2
- RYR1 | c.9332G>A p.R3111Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as rs201145095, COSV100614860, COSV100615465; called by mutect2, varscan2
- SFRP4 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52258098; called by muse, mutect2, varscan2
- SHANK2 | c.3004G>A p.V1002I | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs782310841, COSV53603667; called by muse, mutect2, varscan2
- SKIL | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99378203; called by muse, mutect2, varscan2
- SLC32A1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99461912; called by muse, mutect2, varscan2
- SLC4A7 | c.3002A>C p.K1001T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55396309, COSV55401446; called by muse, mutect2, varscan2
- SYCP2 | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV100698190; called by muse, mutect2, varscan2
- SYNE1 | c.24476A>C p.N8159T (on ENST00000367255 / NM_182961.4; = p.N8088T on NM_033071.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV99561201; called by muse, mutect2, varscan2
- TEKT4 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs1324190552, COSV99726327; called by mutect2, varscan2
- TFAP2D | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV50409741; called by muse, mutect2, varscan2
- TGFB2 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100860053, COSV65109343; called by muse, mutect2, varscan2
- TNFAIP1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs782727172, COSV50228403; called by muse, mutect2, varscan2
- TNXB | c.6647C>T p.P2216L (on ENST00000647633; = p.P1969L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs773297077, COSV100926208; called by muse, mutect2, varscan2
- TRPS1 | c.2401C>T p.R801W (on ENST00000220888 / NM_001330599.2; = p.R814W on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1358796184, COSV55255105; called by muse, mutect2, varscan2
- TTN | c.87137G>A p.G29046D (on ENST00000591111; = p.G21622D on NM_003319.4) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | PolyPhen benign (0.431); catalogued as rs767929728, COSV100605660, COSV60040815; called by muse, mutect2, varscan2
- UBR5 | c.4040C>T p.S1347L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.885); catalogued as rs1046718549, COSV99640612; called by muse, mutect2, varscan2
- UNG | c.805C>T p.R269W (on ENST00000242576 / NM_080911.3; = p.R260W on NM_003362.4) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143034537; called by muse, mutect2, varscan2
- WDR45 | c.836G>A p.R279H (on ENST00000376372 / NM_001029896.2; = p.R280H on NM_007075.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs782296130, COSV100540228; called by muse, mutect2, varscan2
- XIRP2 | c.2323C>G p.H775D (on ENST00000628543; = p.H950D on NM_152381.6) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99741818; called by muse, mutect2, varscan2
- ZBTB20 | c.1423C>T p.L475F (on ENST00000474710 / NM_001164342.2; = p.L402F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100613542; called by muse, mutect2, varscan2
- ZNF518B | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100456668; called by muse, mutect2, varscan2
- ZNF578 | c.324A>C p.K108N | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV69736440; called by muse, mutect2
- LAMA5 | c.10375del p.A3459Qfs*25 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- PAWR | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PCDHB9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH2 | c.1334dup p.N445Kfs*22 | Frame Shift Ins (INS) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.9129T>C p.F3043= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as COSV101315784; called by muse, mutect2, varscan2
- AFF2 | c.744G>A p.A248= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as rs782235447, COSV60657039; called by muse, mutect2, varscan2
- ALPI | c.1293C>T p.S431= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1050452665, COSV99785876; called by muse, mutect2, varscan2
- ARAP2 | c.3402C>T p.S1134= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV100394471; called by muse, mutect2, varscan2
- CWC15 | c.645G>A p.L215= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99688490; called by muse, mutect2, varscan2
- DAB1 | c.1266C>A p.T422= (on ENST00000371231; = p.T389= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs773272378, COSV100976282, COSV64689771; called by mutect2, varscan2
- DAPK2 | c.273C>T p.D91= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs201638173, COSV99977316; called by muse, mutect2, varscan2
- DNAH12 | c.504G>A p.S168= | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as rs150553536, COSV60857539; called by muse, mutect2, varscan2
- EFCAB3 | c.799C>T p.L267= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as rs762405182, COSV100540152; called by muse, mutect2, varscan2
- EHD2 | c.456C>A p.I152= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99621875; called by muse, mutect2, varscan2
- FAM47B | c.1290C>T p.T430= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs1350753109, COSV100264784, COSV61456172; called by muse, mutect2, varscan2
- GFPT2 | c.447C>A p.I149= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV53812173; called by muse, mutect2, varscan2
- JADE2 | c.150C>T p.S50= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs764189413, COSV99252827, COSV99253083; called by muse, mutect2, varscan2
- KIF20B | c.1846C>A p.R616= | Silent (SNP) | VAF 40/217 reads (18%) | catalogued as COSV53309350, COSV99589854; called by muse, mutect2, varscan2
- LAMA5 | c.10374G>A p.G3458= | Silent (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MCM5 | c.819G>A p.K273= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99331634; called by muse, mutect2, varscan2
- MEFV | c.1371G>A p.A457= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs761470030, COSV99560695; called by mutect2, varscan2
- MYH2 | c.3648G>T p.L1216= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV55432148, COSV55444603; called by muse, mutect2, varscan2
- OR10G7 | c.765T>G p.L255= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100389885; called by muse, mutect2, varscan2
- PABPC5 | c.144A>G p.R48= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs760880235, COSV100442309; called by mutect2, varscan2
- PCDHB3 | c.708C>T p.N236= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs782533944, COSV50564702; called by muse, mutect2, varscan2
- PCDHGA1 | c.2121C>T p.F707= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV65296205; called by muse, mutect2, varscan2
- PYROXD1 | c.102A>C p.P34= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV99556483; called by muse, mutect2, varscan2
- ROR1 | c.2628C>A p.S876= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1401971382, COSV100935148, COSV64286707; called by muse, mutect2, varscan2
- SLC39A5 | c.267T>C p.A89= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2
- SYVN1 | c.675G>T p.L225= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99589063; called by muse, mutect2, varscan2
- TSPAN7 | c.660G>A p.A220= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs763482838, COSV99730626; called by muse, mutect2, varscan2
- TTC7B | c.2121C>T p.I707= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs780650246, COSV100127782; called by muse, mutect2, varscan2
- TTN | c.78990T>C p.T26330= (on ENST00000591111; = p.T18906= on NM_003319.4) | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100607357; called by muse, mutect2, varscan2
- TXN2 | c.372C>T p.L124= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs759707924, COSV53398546; called by muse, mutect2, varscan2
- XPO5 | c.984G>A p.A328= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs754664679, COSV99540780; called by muse, mutect2, varscan2
- ZNF280C | c.1078C>A p.R360= | Silent (SNP) | VAF 44/452 reads (10%) | catalogued as rs1429403277, COSV100921220; called by muse, mutect2
- MASP1 | c.1303+4985G>A | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs140933134, COSV99961876; called by mutect2, varscan2
- PRRX1 | c.599+3882G>A | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs375494824; called by mutect2, varscan2
- RPGR | c.2520+1472C>T | Intron (SNP) | VAF 70/300 reads (23%) | catalogued as COSV100139890; called by muse, mutect2, varscan2
- SLC25A3 | c.282+263C>T | Intron (SNP) | VAF 51/190 reads (27%) | catalogued as rs369543793; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48014A>C | Intron (SNP) | VAF 34/323 reads (11%) | catalogued as COSV67442844; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+661C>T | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as rs762217447, COSV53336057, COSV53338664; called by mutect2, varscan2
